Surgical pathology report (de-identified scan), TCGA case TCGA-FB-A4P6, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Asterand, specimen TCGA-FB-A4P6-01A (Primary Tumor).

[page 1 of 2]
Gross Description: A."Hepatic artery lymph node." A 2.0 cm lymph node is sectioned and no obvious metastatic nodules are identified. Half of the lymph node is processed for frozen section interpretation in 1 cassette, along with touch preps for rapid H and E interpretation.

Microscopic Description: Specimen: Head of pancreas, duodenum, stomach, common bile duct

Procedure: Pancreaticoduodenectomy (Whipple resection)

Tumor location: head

Tumor size: 4.5 cm

Histologic type: Ductal adenocarcinoma

Histologic grade: Well differentiated

Microscopic tumor extension: Invades peripancreatic soft tissue

Surgical margins:

Distal pancreas margin: free

Common bile duct margin: free

Duodenum margin: free

Retroperitoneal margin (Uncinate groove): free

Angiolymphatic invasion: Absent

Perineural invasion: Present

Treatment effect: No prior treatment

Lymph nodes:

~~Hepatic artery (A): 1 lymph node negative for metastasis (0/1)~~

Portal (B): 1 lymph node negative for metastasis (0/1)

Peripancreatic, superior: 14 lymph nodes negative for metastases (0/14)

Peripancreatic, inferior: 1 of 9 lymph nodes contain metastasis (1/9)

Pancreaticoduodenal, anterior:

6 lymph nodes negative for metastases (0/6)

ICD-O-3

adenocarcinoma, duct 8500/3

Site: pancreas head c25.0

hw
10/5/12

[page 2 of 2]
Pancreaticoduodenal, posterior:

15 lymph nodes negative for metastases (0/15)

TNM-staging: pT3 pN1 pMx

AJCC stage: IIB

Diagnosis Details: Pancreas (Head): Adenocarcinoma invading into peripancreatic adipose tissue with a lymph node metastasis (1/46)

Comments: Frozen section diagnosis

A. Lymph node (Hepatic artery): Benign

B. Lymph node (Portal): Benign

C. Pancreas duct margin: Negative for malignancy

Formatted Path Reports: PANCREAS TISSUE CHECKLIST

Specimen type: Whipple resection

Tumor site: Head

Tumor size: 4.5 cm

Histologic type: Adenocarcinoma, ductal

Histologic grade: Well differentiated

Tumor extent: Other - Peripancreatic soft tissue

Lymph nodes: 1/46 positive for metastasis (Hepatic artery, portal, superior peripancreatic, i 1/46)

Lymphatic invasion: Absent

Venous invasion: Present

Margins: Uninvolved

Evidence of neo-adjuvant treatment: No

Additional pathologic findings: Pancreas (Head): Adenocarcinoma invading into peripancreatic adipose tissue with a lymph node metastasis (1/46)

Comments: Frozen section diagnosis, A. Lymph node (Hepatic artery): Benign, B. Lymph node (Portal): Benign C. Pancreas duct margin: Negative for malignancy

	Yes	No
Site Discrepancy		☒
Specimen Site Discrepancy		☒
Quantity Discrepancy		☒
Previous History		☒
Consensus Previously Noted		☒

Source: NCI Genomic Data Commons file 5e0e757b-b37d-4b71-8069-09cbbb61bfa4 (TCGA-FB-A4P6.BC211027-32C2-4E6B-BEF6-9B0407966A1E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).